Somatic mutation profile of tumor specimen MP2PRT-PAPXUS-TMP1-A (aliquot MP2PRT-PAPXUS-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPXUS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,426 days).
Specimen MP2PRT-PAPXUS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e40c3fd-1a9e-4355-bbf2-574e96da36e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPXUS-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPXUS-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9de1a988-6d7e-41c7-8644-1108322dcd5d

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP45 | c.2884G>A p.V962I | Missense Mutation (SNP) | VAF 51/589 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1295920597; called by muse, mutect2
- CBLC | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 40/918 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs777753616; called by muse, mutect2
- GPC4 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63697700; called by muse, mutect2
- PCOLCE2 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 108/265 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs745693544, COSV55999593; called by muse, mutect2, varscan2
- PLXND1 | c.3068C>T p.T1023M | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.284); catalogued as rs376531619; called by muse, mutect2
- SNX31 | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 18/537 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs1176105092; called by muse, mutect2
- XAGE2 | c.159_161del p.E53del | In Frame Del (DEL) | VAF 110/340 reads (32%) | catalogued as rs1306510100; called by pindel, varscan2
- AMOTL2 | c.773A>T p.Q258L | Missense Mutation (SNP) | VAF 160/487 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CTNNA3 | c.428A>G p.D143G | Missense Mutation (SNP) | VAF 107/255 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GGA2 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR4D2 | c.572A>C p.D191A | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 136/422 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZNF300 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 172/409 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- ADGRE3 | c.756T>C p.T252= | Silent (SNP) | VAF 25/369 reads (7%) | catalogued as rs780999744, COSV53728080; called by muse, mutect2
- IQGAP1 | c.81T>A p.T27= | Silent (SNP) | VAF 104/246 reads (42%) | called by muse, mutect2, varscan2
- PDZRN4 | c.630C>T p.L210= | Silent (SNP) | VAF 120/358 reads (34%) | catalogued as rs752248309; called by muse, mutect2, varscan2
- PLXNB3 | c.2196G>A p.P732= | Silent (SNP) | VAF 19/577 reads (3%) | catalogued as rs781901361; called by muse, mutect2
- SALL3 | c.1236C>T p.S412= | Silent (SNP) | VAF 56/846 reads (7%) | catalogued as rs201160407, COSV101609953; called by muse, mutect2
- ZFHX3 | c.10317T>C p.P3439= | Silent (SNP) | VAF 136/412 reads (33%) | catalogued as rs754303070; called by muse, mutect2, varscan2
